CCDI case PBCIWG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx.
https://portal.gdc.cancer.gov/cases/ccc7e9b2-c091-483e-b196-6c9315f9aa0c

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Epithelial-myoepithelial carcinoma: ICD-O-3 morphology code: 8562/3; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Age at diagnosis: 16.3 years (5,949 days).

Biospecimens (3 samples)
- Sample 0DSWYR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSWZ3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSWZ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
